TCGA case TCGA-N9-A4Q4 — Uterine Carcinosarcoma (TCGA-UCS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Uterus, NOS; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ffedc8be-1056-4205-b9d9-99b5bdb872db

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Mullerian mixed tumor: ICD-O-3 morphology code: 8950/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 61.8 years (22,575 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; FIGO stage: Stage IIIC; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,089 days (3.0 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 9.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 7.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 8.3.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,089.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 148 cm; BMI: 31.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: Yes; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N9-A4Q4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 540 mg.
  Slide TCGA-N9-A4Q4-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 15; Percent stromal cells: 15; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 5.
- Sample TCGA-N9-A4Q4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N9-A4Q4-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History menopausal hormone therapy: Yes, I have taken menopausal hormone therapy in the past, but no longer do; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; History neoadjuvant treatment: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Uterus; Anatomic organ subdivision: Endometrium; Histologic diagnosis: Uterine Carcinosarcoma/ Malignant Mixed Mullerian Tumor (MMMT): NOS; Surgical approach at diagnosis: Minimally Invasive; Lymph nodes pelvic pos by he: 1; Method initial path diagnosis: Office Endometrial Biopsy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,089 days; disease-specific survival: no event (censored), 1,089 days; disease-free interval: no event (censored), 1,089 days; progression-free interval: no event (censored), 1,089 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N9-A4Q4-01A-11D-A28Q-01): tumor purity 0.94, ploidy 3.27, whole-genome doublings 1.
